MMRF case MMRF_1953 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fb200b79-fa20-48d4-82ea-23395005173b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.0 years (23,021 days); ISS stage: I; Days to last known disease status: 940 days (2.6 years); Days to last follow up: 940 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 640 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 752 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 76 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 0.322 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 394 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.6 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 6.88 mmol/L.
- Day 65 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.53 mg/dL; Immunoglobulin G 5.89 g/L; Immunoglobulin A 0.558 g/L; Immunoglobulin M 0.354 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.341 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 17.8 ×10⁹/L; Absolute Neutrophil 15.9 ×10⁹/L; Platelets 460 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 7.48 mmol/L.
- Day 248 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 8.4 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.269 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 361: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 26.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.4 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 6.27 mmol/L.
- Day 416 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Hemoglobin 6.14 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.85 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 528 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 612 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 7.43 g/L; Immunoglobulin A 0.732 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 147 ×10⁹/L.
- Day 696 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.733 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.45 mmol/L.
- Day 814 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 905 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.4 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 6.49 mmol/L.
- Day 940 (ECOG 1): Hemoglobin 7.87 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 202 ×10⁹/L.

Other clinical attributes
- Day -6: Weight: 93 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1953_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1953_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
